Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8M0, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8M0-01A (Primary Tumor).

Operative Procedure:
Anterior mediastinal dissection.

Specimen Received:
Thymus

Final Pathologic Diagnosis: Per TSS:
Thymus, resection: 20% 80%
Thymoma, WHO mixed type B2 and B3.
-tumor exhibits microscopic invasion of mediastinal adipose tissue.
-tumor abuts inked edge of specimen; however, transection of tumor is not evident.
-size = 3.0 cm.
-three benign lymph nodes recovered from specimen.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

The specimen is received in formalin and labeled "A, thymus" and consists of an 18.5 x 10.0 x 4.0 cm portion of lobulated tan-yellow fatty tissue, partially surfaced by mediastinal pleura. Present within the fat is a 3.0 x 2.5 x 2.5 cm firm, tan white well circumscribed mass. The cut surface of the mass shows a tan-white fibrous capsule that ranges from 0.2 to 0.6 cm thick. The center of the mass is tan-pink and soft with scattered hemorrhagic foci. The mass abuts both the mediastinal pleura, as well as the inked soft tissue margin. Scattered around the mass are multiple soft pink fragments of questionable thymic tissue. One area of the mass appears to be infiltrating into the adjacent soft tissue. Examination of the attached fat reveals a tan-yellow lobulated cut surface. No additional masses are noted. Three lymph nodes are identified.

Representative sections are submitted as follows:

- 1 mass to inked soft tissue margin;
- 2 mass to mediastinal pleura;
- 3 area mass infiltration into adjacent soft tissue;
- 4-5 additional mass;
- 6 questionable thymus tissue;
- 7 two whole lymph nodes;
- 8 one lymph node bisected.
- 9-14 additional tumor

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

Surgical Pathology Report

Taken: DOB: (Age: Gender: F Race: White

ALL TCD-0-3
Thymoma, type B3
malignant 8585/3
path Thymoma, mixed type B2+B3,
malignant 8582/3
Site: Thymus C379
JPS 6/10/14

Criteria	10/16/14	11/16/14
Diagnostic discrepancy	10/16/14	11/16/14
USAA Discrepancy		
Tumor Malignancy history		
Metastatic/Synchronous Primary Malignancy		
Site to (circle):	SC	11/16/14
Review of Initials		

Source: NCI Genomic Data Commons file 5176c9c1-1956-409a-a7e5-5430c414a364 (TCGA-X7-A8M0.DC4064BE-1218-402A-809C-92D77B1D5200.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).